CCDI case PBCBJJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5014d645-c8d8-4554-bf8c-7358912e287a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 17.9 years (6,556 days).

Biospecimens (3 samples)
- Sample 0DNMA0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNMAF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNMAQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
